Gene-level copy-number profile of tumor specimen TARGET-10-PATNIA-09A from TARGET case TARGET-10-PATNIA, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.6 years (2,401 days).
Specimen TARGET-10-PATNIA-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-ALL-P2.b19d8d77-a58e-5c5e-ad3a-62f55ff40447.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-10-PATNIA-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 368 have no estimate.
https://portal.gdc.cancer.gov/files/b1b8edc2-d67f-497b-8a58-cf1f662c8295

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 536; copy number 1: 1,487; copy number 2: 57,735; copy number 3: 258; copy number 4: 109; copy number 5: 130.

Homozygous deletions (total copy number 0; autosomes only): 16 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:38,256,337–38,340,998, 15 genes: TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7, TRGV6.
- chr7:38,345,030–38,345,499, 1 gene: TRGV5P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 130 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:88,811,186–88,861,563, 1 gene, copy number 5 (within-gene range 2–5): AC244205.1.
- chr2:88,857,161–90,005,629, 71 genes, copy number 5 (broad region; genes not listed).
- chr15:21,990,074–23,407,335, 58 genes, copy number 5 (within-gene range 4–5): AC134980.1, OR11H3P, AC134980.2, OR11K1P, OR4Q1P, OR4H6P, OR4M2, OR4N4, OR4N3P, AC010760.1, RPS8P10, IGHV1OR15-1, IGHV1OR15-3, IGHV4OR15-8, IGHV1OR15-4, AC025884.3, MIR1268A, AC025884.2, AC025884.1, AC100757.2, AC100757.1, SPATA31E3P, GOLGA8EP, RN7SL545P, AC100757.3, GOLGA6L22, HERC2P7, HERC2P2, GOLGA8IP, RN7SL495P, WHAMMP3, AC138649.2, AC138649.5, AC138649.4, PDCD6IPP1, AC138649.3, AC138649.1, AC011767.1, NIPA1, NIPA2, CYFIP1, TUBGCP5, ELMO2P1, GOLGA6L1, AC116165.1, GOLGA8DP, RN7SL106P, ABCB10P1, AC116165.2, MIR4509-1, AC116165.3, AC242376.1, HERC2P7, AC100756.2, AC100756.1, GOLGA8S, RN7SL536P, AC100756.3.

Autosomal genes at a single copy (total copy number 1): 1,394. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
